Somatic mutation profile of tumor specimen 0DD6S2 from CCDI case PBBNDK, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female; Vital status: Alive; Primary diagnosis: Dermatofibrosarcoma protuberans, NOS; Tissue or organ of origin: Lower limb, NOS; Age at diagnosis: 8.4 years (3,053 days).
Specimen 0DD6S2: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 54ec7704-a647-46d9-af69-49d98a93aa86.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DD6S3 (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/bd7528f6-153c-499f-b94d-c8dbba8b8efa

The open-access MAF lists 2 somatic variants for this specimen: 2 protein-altering or splice-affecting.
By variant classification: Missense Mutation 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CXorf56 | c.170G>A p.R57H | Missense Mutation (SNP) | VAF 138/464 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.963); catalogued as rs145119663; called by muse, varscan2
- TMEM163 | c.346G>A p.A116T | Missense Mutation (SNP) | VAF 174/516 reads (34%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.992); catalogued as rs759386524, COSV56106811; called by muse, varscan2
